Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3967, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3967-01A (Primary Tumor).

Diagnosis:

Resected colon sample with two moderately differentiated, invasive adenocarcinoma of the colorectal type, measuring max 5 cm in diameter, both with infiltration of the pericolic fatty tissue. Two local lymph node metastases. Tumor-free colon resection margins. Tumor-free mesenteric resection margin.

The tumor stage is: pT3, (2), pN1 (2/33) pNX; G2, L0, V0, local R0.

Source: NCI Genomic Data Commons file 19dcee72-b1a1-4fab-85ff-4873213f1317 (TCGA-AA-3967.B47A1EB7-36F7-4203-BFCC-C8BCA5551358.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).